Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A6E2, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A6E2-01A (Primary Tumor).

[page 1 of 4]
Specimen Date/Time:

** Case imported from legacy computer system. The format of this report does not match the original case. **
** For cases prior to the section "SPECIMEN" may have been added. **

SUPPLEMENTAL REPORT 2

DIAGNOSIS:

(C) PROSTATE AND SEMINAL VESICLES AND PERIRECTAL NODULE:
Special stains for organisms performed on the
caseating granuloma present in the "perirectal nodule" are negative for
organisms.

This supplemental report is being issued to give the results of additional
studies. This report does not alter the previously issued diagnosis.

Entire report and diagnosis completed by:
Report released by:

path ICD-O-3
Adenocarcinoma NOS
C&CF 8140/3
Adenocarcinoma, acinar
8140/3
Site Prostate NOS
C61.9
JA 5/21/13

SUPPLEMENTAL REPORT

DIAGNOSIS:

- (C) PROSTATE AND SEMINAL VESICLES AND PERIRECTAL NODULE:
PROSTATIC ADENOCARCINOMA, GLEASON SCORE 7 (3+4). (SEE COMMENT)
CARCINOMA EXTENDING TO THE ANTERIOR BLADDER NECK MARGIN OF
RESECTION. (SEE COMMENT)
FINAL BLADDER NECK MARGIN OF RESECTION (SPECIMENS F & G), FREE OF
TUMOR.
No extra prostatic extension present.
PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH GRADE.
Right and left seminal vesicles, no tumor present.
Segments of right and left vasa deferentia, no tumor present.
Focal granulomas in prostatic parenchyma. (See Comment)
Periprostatic nodule with necrotizing granulomatous inflammation.
(See Comment)
- (F) ADDITIONAL LEFT BLADDER NECK MARGIN:
Smooth muscle focally lined by urothelium consistent with bladder
neck, no tumor present. Few glands consistent with prostatic glands
present. No prostatic glands present at margin.
- (G) ADDITIONAL RIGHT BLADDER NECK MARGIN:
Smooth muscle and adipose tissue consistent with bladder neck tissue,
no tumor present.
No prostatic glands present.

COMMENT:

The prostate gland contains three separate foci of prostatic adenocarcinoma,
one in the transition zone and two in the peripheral zone. The dominant tumor
focus is located on the mid anterior and left transition zone. This tumor
focus measures 2.0 x 2.0 cm in the largest cross sectional dimension and it is
present in the four cross sections of the prostate and extensively in the apex
and base regions. This tumor focus extends in the prostatectomy specimen to

[page 2 of 4]
Specimen Date/Time:

the right anterior bladder neck margin of resection. The extent of marginal involvement is 4.0 mm. It should be noted that additional, separately submitted specimens from the bladder neck (parts F and G) are free of tumor.

The peripheral zone foci are located in the left lateral and left posterolateral peripheral zone. These tumor foci measure 0.3 x 0.2 and 0.2 x less than 0.1 mm and each is present in one cross section. These tumor foci are confined to the prostate and the margins of resection are free of tumor.

The periprostatic nodule present on the right posterior surface (base level) of the prostate is composed of necrotizing granulomatous inflammation. It cannot be established with certainty if the process is located in a periprostatic lymph node. A few granulomas without central necrosis and one or two with focal necrosis are present within the prostate proper. Special stains for organisms performed on sections from the periprostatic nodule are pending. A supplemental report will follow.

GROSS:

(C) PROSTATE AND SEMINAL VESICLES - A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (5.2 x 3.7 x 4.0 cm, 48 grams, post fixation) has the usual shape. The soft tissue present along the right and left posterolateral aspects of the prostate appears symmetrical. A firm nodule is located in the right posterior surface of the prostate in the base region. This nodule measures 2.3 x 2.0 x 1.0 cm. The center of the nodule contains soft yellow material. Serial cross sections demonstrate possible carcinoma in the left transition zone of the first cross section. No unequivocal tumor is identified in the peripheral zone.

The seminal vesicles and segments of vasa deferentia are symmetrical and grossly free of tumor.

SECTION CODE: C1, left transition zone, punch biopsy; C2, possible carcinoma left transition zone; C3, C4, right seminal vesicle and segment of right vas deferens from the base towards the tip; C5, C6, left seminal vesicle and segment of left vas deferens from the base towards the tip; C7, C8, prostatic base right border; C9, C10, prostatic base right posterior border; C11-C21, prostatic base central portion; C22, C23, prostatic base left border; C24, C25, prostatic base left posterior border; C26, C27, apex anterior; C28-C30, apex left; C31-C33, apex posterior; C34, apex right; C35, detached portions of margin of resection according to specimen radiograph; C36-C57, sections of the four cross sections of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black. Orange ink (C57) denotes a surface which is not a true margin of resection.

(F) ADDITIONAL LEFT BLADDER NECK MARGIN (LONG STITCH MARKS FINAL MARGIN) - A fragment of tan-gray tissue (3.3 x 0.9 x 0.3 cm). There are multiple long sutures along one surface of the fragment. Multiple small sutures are present on the opposite surface. The surface corresponding to the long sutures is inked red. The specimen is serially sectioned perpendicular to the surface inked red and submitted as F1 and F2.

(G) ADDITIONAL RIGHT BLADDER NECK MARGIN (LONG STITCH IS FINAL MARGIN) - A fragment of firm tan-gray tissue (2.8 x 0.5 x 0.3 cm). Multiple long sutures are present on one surface of the specimen and multiple short sutures on the opposite surface. The surface corresponding to the long sutures is inked

[page 3 of 4]
[REDACTED]
[REDACTED]
[REDACTED]

yellow. The specimen is serially sectioned in a plane perpendicular to the surface inked yellow and submitted entirely as G1 and G2.

Entire report and diagnosis completed by:
Report released by:

DIAGNOSIS

- (A) RIGHT PELVIC LYMPH NODES:
Three Lymph nodes, no tumor present.
- (B) LEFT PELVIC LYMPH NODES:
Two lymph nodes, no tumor present.
- (C) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.
- (D) RIGHT BLADDER NECK, RULE OUT PROSTATE:
Smooth muscle consistent with bladder neck, no tumor present.
No prostatic glands present.
- (E) LEFT BLADDER NECK, RULE OUT PROSTATE:
PROSTATIC ADENOCARCINOMA INVOLVING SMOOTH MUSCLE CONSISTENT WITH
BLADDER NECK.
- (F) ADDITIONAL LEFT BLADDER NECK MARGIN:
Supplemental report to follow.
- (G) ADDITIONAL RIGHT BLADDER NECK MARGIN:
Supplemental report to follow.
- (H) LEFT BLADDER NECK, DEEPEST MARGIN:
Smooth muscle focally lined by urothelium consistent with bladder
neck, no tumor present.
No prostatic glands present.

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION

(A) RIGHT PELVIC LYMPH NODES - A single piece of fatty tissue (5.0 x 3.0 x 0.8 cm). Two possible lymph nodes are identified in the tissue, (3.0 x 0.7 x 0.5 cm, and 2.0 x 0.5 x 0.4 cm). The specimens are bisected and entirely submitted.

SECTION CODE: A1, one intact lymph node; A2, one bisected lymph node; A3, one bisected lymph node.

(B) LEFT PELVIC LYMPH NODES - A single piece of fatty tissue which measures 6.0 x 4.0 x 2.0 cm. Two possible lymph nodes are identified in the tissue ranging in size from 2.0 to 2.5 cm in greatest dimension. These lymph nodes are entirely submitted in three cassettes.

SECTION CODE: B1, one bisected lymph node; B2, B3, one lymph node.

(C) PROSTATE AND SEMINAL VESICLES - Supplemental report to follow.

(D) RIGHT BLADDER NECK, RULE OUT PROSTATE - A gray-tan soft tissue fragment 0.5 x 0.3 x 0.3 cm. The specimen is serially sectioned and submitted in toto for frozen section B.

*FS/DX: THICK BUNDLES OF SMOOTH MUSCLE, NO PROSTATIC GLANDS OR TUMOR PRESENT.

(E) LEFT BLADDER NECK, RULE OUT PROSTATE - A single gray-tan soft tissue fragment (0.6 x 0.4 x 0.4 cm). The specimen is serially sectioned and submitted in toto for frozen section as E.

*FS/DX: PROSTATIC ADENOCARCINOMA IN THICK BUNDLES OF SMOOTH MUSCLE,

[page 4 of 4]
Specimen Date/Time:

CONSISTENT WITH BLADDER NECK.

(F) ADDITIONAL LEFT BLADDER NECK MARGIN - Supplemental report to follow.

(G) ADDITIONAL RIGHT BLADDER NECK MARGIN - Supplemental report to follow.

(H) LEFT BLADDER NECK, DEEPEST MARGIN FOR FROZEN SECTION - A single gray-tan soft tissue fragment, 0.5 x 0.5 x 0.3 cm. Submitted in toto for frozen section as H.

*FS/DX: SMOOTH MUSCLE, NO PROSTATIC GLANDS OR TUMOR PRESENT.

SNOMED CODES

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 3173dd76-65eb-42af-bdf0-edb040ea1718 (TCGA-KK-A6E2.84DBE486-DFA5-4FBC-BA8F-E10CC0247645.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).